Somatic mutation profile of tumor specimen 0D9MJI from CCDI case PBBINB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.8 years (3,206 days).
Specimen 0D9MJI: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7cc71a5c-0739-496d-88eb-c058c9ddfff8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0D9MJV (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/27e5f67d-e487-4f3f-8448-21b721409236

The open-access MAF lists 21 somatic variants for this specimen: 16 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 3, Splice Site 1, Nonsense Mutation 1, Frame Shift Del 1, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.94G>T p.D32Y | Missense Mutation (SNP) | VAF 60/194 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs28931588, COSV62687956, COSV62688134, COSV62688665; ClinVar: pathogenic / likely pathogenic /  other; called by mutect2, varscan2
- ADGB | c.4537+1G>A p.X1513_splice | Splice Site (SNP) | VAF 24/41 reads (59%) | catalogued as rs370591540; called by muse, mutect2, varscan2
- CFAP54 | c.5281del p.E1761Kfs*3 | Frame Shift Del (DEL) | VAF 30/82 reads (37%) | catalogued as COSV61570628; called by mutect2, varscan2
- GLG1 | c.2345C>T p.T782M | Missense Mutation (SNP) | VAF 79/296 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as rs754176332, COSV52669748; called by muse, mutect2, varscan2
- PKD2L1 | c.1294G>T p.A432S | Missense Mutation (SNP) | VAF 73/221 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.864); catalogued as COSV58399021; called by muse, mutect2, varscan2
- RYR1 | c.5464G>A p.G1822S | Missense Mutation (SNP) | VAF 55/126 reads (44%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.588); catalogued as rs1169294876, COSV100614822, COSV62113655; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SAMD4A | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 66/191 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.926); catalogued as rs753545766, COSV99200607; called by muse, mutect2, varscan2
- SMARCA4 | c.3574C>A p.R1192S | Missense Mutation (SNP) | VAF 235/608 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60787617, COSV60789344; called by muse, mutect2, varscan2
- ZC3H7B | c.889G>A p.G297S | Missense Mutation (SNP) | VAF 126/330 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.047); catalogued as rs748706918; called by muse, mutect2, varscan2
- AL662899.2 | c.250C>T p.H84Y | Missense Mutation (SNP) | VAF 149/217 reads (69%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IQCE | c.35C>T p.T12M | Missense Mutation (SNP) | VAF 81/294 reads (28%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- LTBP3 | c.3832G>A p.G1278S (on ENST00000301873 / NM_001130144.3; = p.G1231S on NM_021070.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 160/461 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NES | c.3116A>G p.Q1039R | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.781); called by mutect2, varscan2
- PDE3A | c.3243G>T p.Q1081H | Missense Mutation (SNP) | VAF 11/220 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); called by muse, mutect2
- TIGD3 | c.731T>A p.L244* | Nonsense Mutation (SNP) | VAF 26/81 reads (32%) | called by muse, mutect2, varscan2
- ZBTB12 | c.161G>A p.C54Y | Missense Mutation (SNP) | VAF 62/86 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- GCAT | c.1254G>T p.L418= | Silent (SNP) | VAF 179/476 reads (38%) | called by muse, mutect2, varscan2
- KHK | c.126C>T p.N42= | Silent (SNP) | VAF 53/240 reads (22%) | catalogued as rs1418153355, COSV99566583; called by muse, mutect2, varscan2
- SHH | c.156C>A p.A52= | Silent (SNP) | VAF 4/42 reads (10%) | called by mutect2, varscan2
- CLPTM1 | c.1038+30C>A | Intron (SNP) | VAF 11/59 reads (19%) | called by muse, mutect2, varscan2
- CTSA | c.-54G>A | 5'UTR (SNP) | VAF 161/472 reads (34%) | catalogued as rs377390291; called by muse, mutect2, varscan2
